Somatic mutation profile of tumor specimen TARGET-10-PANWKP-09A (aliquot TARGET-10-PANWKP-09A-01D) from TARGET case TARGET-10-PANWKP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,256 days).
Specimen TARGET-10-PANWKP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b00ee621-2981-4d64-b107-544356c5a096.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWKP-10A (Blood Derived Normal), aliquot TARGET-10-PANWKP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b152cada-8706-4082-a707-44724a4a4d3f

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2, Intron 2, 5'UTR 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD10 | c.3040C>T p.R1014C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1377342033, COSV52660033; called by muse, mutect2, varscan2
- KIAA1841 | c.1489C>A p.P497T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV54375232; called by muse, mutect2
- MDFIC | c.112A>T p.N38Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.66); catalogued as rs188705710; called by muse, mutect2, varscan2
- NCAM2 | c.2389C>A p.L797M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1467124936; called by muse, mutect2, varscan2
- PCDHA5 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs529947743, COSV65353301; called by muse, mutect2, varscan2
- PCDHA5 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as rs1554129666, COSV65350345; called by muse, mutect2, varscan2
- SDK2 | c.2002G>A p.V668I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs754435436, COSV66190084; called by muse, mutect2
- BOC | c.2628C>A p.C876* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- GASK1B | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- MAP2 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K4 | c.1175C>A p.A392E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MUC17 | c.8495C>A p.T2832K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- OR8B4 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.074); called by muse, mutect2
- PLK4 | c.1023C>A p.N341K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- RRAGA | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CACNA2D1 | c.1410C>T p.T470= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as rs771969809, COSV100667124, COSV62374396; called by muse, mutect2, varscan2
- NDST3 | c.2166C>T p.Y722= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs370784337; called by muse, mutect2, varscan2
- TAF1C | c.1479G>T p.L493= | Silent (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- IGHV1-45 | chr14:106506995 ins GGCCTA | 3'Flank (INS) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- OR5P1P | n.235G>T | RNA (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- PAX6 | c.1032+129C>T | Intron (SNP) | VAF 5/22 reads (23%) | catalogued as rs750513256; called by muse, mutect2, varscan2
- PHACTR1 | c.251-119691C>A | Intron (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- ZFHX3 | c.-811C>T | 5'UTR (SNP) | VAF 13/42 reads (31%) | catalogued as rs754917691, COSV101637440; called by muse, mutect2
- ZNF875 | c.-1C>A | 5'UTR (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
